Gene-level copy-number profile of tumor specimen C3L-07645-05 from CPTAC case C3L-07645, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIIC; Tumor grade: G2; Age at diagnosis: 65.1 years (23,762 days).
Specimen C3L-07645-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ebbb3689-d960-44ac-a6ed-5c80881fbfb0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-07645-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/be7d3c29-fbb0-44ca-98de-1db5d3277695

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 6; copy number 1: 959; copy number 2: 18,989; copy number 3: 16,896; copy number 4: 17,785; copy number 5: 306; copy number 6: 1,815; copy number 7: 1,510; copy number 8: 394; copy number 9: 15; copy number 10: 48; copy number 11: 26; copy number 12: 22; copy number 13: 14; copy number 15: 6; copy number 17: 9; copy number 18: 12; copy number 19: 5; copy number 20: 6; copy number 22: 4; copy number 23: 2; copy number 24: 8; copy number 25: 3; copy number 26: 7; copy number 27: 8; copy number 29: 6; copy number 30: 35; copy number 38: 9.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:49,096–88,208, 2 genes: BNIP3P41, ZNF595.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 245 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:26,254,104–27,171,811, 13 genes, copy number 9 (within-gene range 7–9): CDK8, AL159159.1, WASF3, RPS3AP44, WASF3-AS1, AL159978.1, GPR12, FGFR1OP2P1, AL160035.1, RPS21P8, RPS20P32, USP12, AL158062.1.
- chr13:28,300,346–28,495,145, 1 gene, copy number 9: FLT1.
- chr13:30,022,021–31,483,699, 34 genes, copy number 10: AL354674.1, LINC00365, LINC00384, LINC00385, AL157770.1, KATNAL1, RNU6-64P, PRDX2P1, LINC00427, LINC00426, AL356750.1, LINC01058, UBE2L5, HMGB1, AL353648.1, RBM22P2, MFAP1P1, PTPN2P2, USPL1, Metazoa_SRP, ALOX5AP, LINC00398, LINC00545, TEX26-AS1, MEDAG, TEX26, AL353680.1, LINC01066, WDR95P, HSPH1, B3GLCT, ANKRD26P4, AL161616.2, AL161616.1.
- chr18:21,242,242–21,525,417, 4 genes, copy number 11: GREB1L, AC015878.2, AC015878.1, AC011774.1.
- chr18:21,612,314–23,260,467, 41 genes, copy number 13–38 (within-gene range 2–42): SNRPD1, ABHD3, AC106037.2, AC106037.3, MIR320C1, MIB1, AC106037.1, Y_RNA, RN7SL233P, SNORA73, MIR133A1HG, MIR133A1, MIR1-2, AC103987.1, AC103987.2, RNU6-1038P, AC103987.3, RNA5SP451, LINC01900, AC091043.1, RNU6ATAC20P, GATA6-AS1, GATA6, AC091588.1, RNU6-702P, AC091588.3, AC091588.2, AC027449.1, CTAGE1, ATP7BP1, RPS4XP18, RNU6-1032P, AC090912.1, AC090912.2, RBBP8, AC090912.3, UBE2CP2, MIR4741, RN7SL745P, Y_RNA, CABLES1.
- chr18:31,962,178–31,986,087, 3 genes, copy number 18: PGDP1, AC009831.2, AC009831.4.
- chr18:32,091,874–32,131,561, 2 genes, copy number 13 (within-gene range 2–13): RNF138, AC011825.2.
- chr18:32,470,288–32,745,567, 1 gene, copy number 11 (within-gene range 2–11): AC025887.2.
- chr18:32,672,673–35,143,470, 18 genes, copy number 10–15 (within-gene range 6–15): KLHL14, AC012123.1, AC012123.2, AC090371.2, CCDC178, AC090371.1, AC091198.1, ASXL3, NOL4, Y_RNA, AC104985.3, AC104985.1, AC104985.2, DTNA, AC013290.1, AC022601.1, AC068506.1, MAPRE2.
- chr18:35,716,370–35,966,118, 5 genes, copy number 13: AC090229.1, NRBF2P1, MIR187, MIR3929, AC118757.1.
- chr18:36,297,714–36,780,055, 2 genes, copy number 12 (within-gene range 2–12): FHOD3, AC055840.1.
- chr18:39,016,047–39,034,110, 2 genes, copy number 12: RN7SKP182, RNU6-706P.
- chr18:41,789,162–41,819,421, 2 genes, copy number 9–11: NPM1P1, AC011225.1.
- chr18:44,676,927–44,679,717, 1 gene, copy number 12: SETBP1-DT.
- chr18:45,212,995–46,266,992, 21 genes, copy number 12–26: SLC14A2, SLC14A2-AS1, AC021517.1, AC021517.3, AC091151.2, AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25.
- chr18:46,476,972–47,102,243, 9 genes, copy number 11–15 (within-gene range 6–15): LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2.
- chr18:47,032,572–47,703,745, 16 genes, copy number 11–23: ELOA2, AC012254.5, AC012254.1, AC012254.3, HDHD2, AC012254.2, AC012254.4, IER3IP1, SKOR2, RNU6-1131P, MIR4527HG, MIR4527, AC102797.2, AC102797.1, TPMTP1, AC026898.1.
- chr18:48,475,487–50,207,278, 48 genes, copy number 11–30: RNA5SP456, AC024288.1, POLR3GP2, CTIF, AC048380.2, AC048380.3, MIR4743, AC048380.1, AC022919.1, AC093567.1, SMAD7, AC114684.1, AC016866.3, AC016866.1, DYM, MIR4744, AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1, AC090227.3, ACAA2, AC090227.2, SNHG22, SCARNA17, AC090227.1, MYO5B, Y_RNA, RNA5SP457, AC091044.1, ADAD1P2, AC105224.1, MIR4320, RN7SL310P.
- chr18:51,346,249–52,339,025, 7 genes, copy number 10–12: LINC01630, SS18L2P2, AC109315.1, RSL24D1P9, AC027216.1, RPS8P3, AC016383.1.
- chr18:53,480,825–53,629,990, 3 genes, copy number 10–17 (within-gene range 6–17): LINC01917, LINC01919, RPL29P32.
- chr18:69,831,158–70,554,100, 12 genes, copy number 25–38 (within-gene range 2–38): CD226, RTTN, AC021701.1, SOCS6, LINC01909, LIVAR, LINC01910, LARP7P3, RPS2P6, AC091305.1, AC091646.1, RN7SL795P.

Autosomal genes at a single copy (total copy number 1): 959. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
